Somatic mutation profile of tumor specimen TCGA-BF-A9VF-01A (aliquot TCGA-BF-A9VF-01A-11D-A372-08) from TCGA case TCGA-BF-A9VF, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 77.5 years (28,312 days).
Specimen TCGA-BF-A9VF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80606d36-3559-4811-a0ad-f1ba0379f723.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-A9VF-10A (Blood Derived Normal), aliquot TCGA-BF-A9VF-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2199b042-4d39-4584-bb5c-50cda194771c

The open-access MAF lists 109 somatic variants for this specimen: 65 protein-altering or splice-affecting, 41 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 41, Nonsense Mutation 7, Intron 2, Splice Region 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/126 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- A4GALT | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV99966732; called by muse, mutect2, varscan2
- AC011448.1 | c.171C>T p.R57= | Splice Region (SNP) | VAF 11/24 reads (46%) | catalogued as COSV99389229; called by muse, mutect2, varscan2
- ADCY9 | c.2840C>T p.T947I | Missense Mutation (SNP) | VAF 88/152 reads (58%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs758989525, COSV99570732; called by muse, mutect2, varscan2
- AMY2A | c.692A>T p.N231I | Missense Mutation (SNP) | VAF 114/611 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV101340668; called by muse, mutect2, varscan2
- ANKRD30A | c.3385G>A p.E1129K (on ENST00000611781; = p.E1073K on NM_052997.2) | Missense Mutation (SNP) | VAF 43/49 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV64607971; called by muse, mutect2, varscan2
- APOBEC3F | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs745372879, COSV57910629; called by muse, mutect2, varscan2
- BRSK1 | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.68); PolyPhen benign (0.262); catalogued as COSV100474517; called by muse, mutect2, varscan2
- C12orf60 | c.666A>C p.L222F | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV99966965; called by muse, mutect2, varscan2
- C12orf60 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as rs1238650898, COSV57452486, COSV99966966; called by muse, mutect2, varscan2
- C17orf97 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.026); catalogued as COSV64076129; called by muse, mutect2, varscan2
- C2CD3 | c.2842C>T p.R948* | Nonsense Mutation (SNP) | VAF 44/130 reads (34%) | catalogued as rs1437215284, COSV58089808; called by muse, mutect2, varscan2
- CLCN1 | c.2525C>T p.S842L | Missense Mutation (SNP) | VAF 109/180 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867453650, COSV58368229; called by muse, mutect2, varscan2
- CLEC4F | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 85/178 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV55479470; called by muse, mutect2, varscan2
- CLPB | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 42/61 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); catalogued as rs758704489, COSV99578572; called by muse, mutect2, varscan2
- COL13A1 | c.1861G>A p.D621N (on ENST00000398978 / NM_001130103.2; = p.D549N on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/163 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100637731; called by muse, mutect2, varscan2
- COL6A2 | c.2566G>A p.V856M | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368160013, COSV52424872; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- DNAJC13 | c.4586C>T p.A1529V | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV99607914; called by muse, mutect2, varscan2
- DNAJC14 | c.1648G>A p.D550N | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as COSV99670846; called by muse, mutect2, varscan2
- EPB41 | c.1075C>T p.Q359* (on ENST00000343067 / NM_001166005.2; = p.Q150* on NM_004437.4) | Nonsense Mutation (SNP) | VAF 54/118 reads (46%) | catalogued as COSV100549299; called by muse, mutect2, varscan2
- EXD1 | c.455G>A p.R152K | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100153800, COSV59253230; called by muse, mutect2, varscan2
- FAT1 | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 74/151 reads (49%) | catalogued as rs946092065, COSV101499594; called by muse, mutect2, varscan2
- FBXW12 | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV99601786; called by muse, mutect2, varscan2
- FGD5 | c.3332G>A p.G1111E | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53240723, COSV53250279, COSV99549019; called by muse, mutect2, varscan2
- GPATCH1 | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs747262991, COSV99404277; called by muse, mutect2, varscan2
- GRIA2 | c.294T>G p.N98K | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99645072, COSV99645665; called by muse, mutect2, varscan2
- HCFC2 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99983241; called by muse, mutect2, varscan2
- HEPH | c.2758G>A p.E920K (on ENST00000343002; = p.E653K on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/52 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57961362; called by muse, mutect2, varscan2
- IFIT1 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV100878762; called by muse, mutect2, varscan2
- IGKV1-16 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 101/205 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); catalogued as rs1173819368; called by muse, mutect2, varscan2
- IGLV11-55 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as COSV101135349; called by muse, mutect2, varscan2
- IKZF2 | c.1561G>A p.G521R | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100563781, COSV100563803; called by muse, mutect2, varscan2
- INTS14 | c.1535G>A p.G512E (on ENST00000313182 / NM_001366360.2; = p.G433E on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.131); catalogued as COSV99971271; called by muse, mutect2, varscan2
- JARID2 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as rs373104387; called by muse, mutect2, varscan2
- KBTBD8 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.255); catalogued as COSV99805867; called by muse, mutect2, varscan2
- KCNA5 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as COSV99364133; called by muse, mutect2, varscan2
- KRT32 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99863145; called by muse, mutect2, varscan2
- LRCH3 | c.2130A>G p.V710= | Splice Region (SNP) | VAF 63/144 reads (44%) | catalogued as rs1482835943, COSV100605221; called by muse, mutect2, varscan2
- LRRC37A | c.4267C>T p.P1423S | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (1); PolyPhen probably damaging (0.968); catalogued as rs1483445616, COSV100208259; called by muse, mutect2, varscan2
- MAMLD1 | c.1790A>T p.Q597L | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.529); catalogued as COSV53376712; called by muse, mutect2
- MUC17 | c.11755C>T p.P3919S | Missense Mutation (SNP) | VAF 57/228 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.103); catalogued as rs865774883, COSV60281359; called by muse, mutect2, varscan2
- MYH8 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 71/153 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs779991062, COSV67961263, COSV67964611; called by muse, mutect2, varscan2
- NLGN4Y | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV100197067; called by muse, mutect2, varscan2
- NLRP14 | c.1618C>T p.R540* | Nonsense Mutation (SNP) | VAF 38/42 reads (90%) | catalogued as rs373865085, COSV100205215, COSV55065906; called by muse, mutect2, varscan2
- NPAP1 | c.3334G>A p.G1112R | Missense Mutation (SNP) | VAF 103/165 reads (62%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.156); catalogued as COSV100276006; called by muse, mutect2, varscan2
- PEA15 | c.134G>A p.W45* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as COSV100470381, COSV100470741; called by muse, mutect2, varscan2
- PEA15 | c.135G>A p.W45* | Nonsense Mutation (SNP) | VAF 21/73 reads (29%) | catalogued as COSV100470743; called by muse, mutect2, varscan2
- PKHD1 | c.3766C>A p.Q1256K | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.92); PolyPhen benign (0.022); catalogued as rs1011451342, CD100432, COSV100584290; called by muse, mutect2
- PKP2 | c.2335C>T p.P779S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV50754352; called by muse, mutect2, varscan2
- PRKG2 | c.1545-1G>A p.X515_splice | Splice Site (SNP) | VAF 46/85 reads (54%) | catalogued as COSV100020403; called by muse, mutect2, varscan2
- RAPGEF2 | c.899T>G p.L300W | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100031551; called by muse, mutect2, varscan2
- REG3A | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as rs771324295, COSV100532887, COSV59411459; called by muse, mutect2, varscan2
- RGS12 | c.4013C>T p.A1338V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV100123254; called by muse, mutect2, varscan2
- SART3 | c.1643C>T p.A548V (on ENST00000228284; = p.A530V on NM_014706.4) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.325); catalogued as COSV99934358; called by muse, mutect2, varscan2
- SGIP1 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 107/257 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99392598; called by muse, mutect2, varscan2
- SLC5A8 | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1346555854, COSV73311409; called by muse, mutect2, varscan2
- TAS1R2 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV100946329, COSV64744323; called by muse, mutect2, varscan2
- THSD7B | c.2395C>T p.R799W | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs375482277; called by muse, mutect2, varscan2
- TMEM131L | c.848A>G p.H283R | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as rs1025522380, COSV99548021; called by muse, mutect2, varscan2
- TNNT1 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755856894, COSV99402995; called by muse, mutect2, varscan2
- UGT2B15 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 86/215 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100592431; called by muse, mutect2, varscan2
- VPS13B | c.5119A>C p.K1707Q | Missense Mutation (SNP) | VAF 54/60 reads (90%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.476); catalogued as COSV100663212, COSV62151830; called by muse, mutect2, varscan2
- ZDHHC17 | c.824A>G p.N275S | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV100602231; called by muse, mutect2, varscan2
- ZNF239 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.352); catalogued as rs868142686, COSV60018361; called by muse, mutect2, varscan2
- ZNF711 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 31/33 reads (94%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.565); catalogued as rs867207957, COSV52157903; called by muse, mutect2, varscan2
- ACMSD | c.444C>T p.N148= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as rs140988963; called by muse, mutect2, varscan2
- AMER1 | c.2421G>T p.V807= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV100366919; called by muse, mutect2, varscan2
- ATP4A | c.2136C>T p.I712= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs748500240, COSV52865971, COSV52868425; called by muse, mutect2, varscan2
- BTD | c.1425C>T p.I475= | Silent (SNP) | VAF 48/95 reads (51%) | catalogued as COSV57728752; called by muse, mutect2, varscan2
- CA11 | c.327C>T p.F109= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV99320826; called by muse, mutect2, varscan2
- CRB1 | c.141T>C p.D47= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV100959279; called by muse, mutect2, varscan2
- DNMT3L | c.199C>T p.L67= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV99533419; called by muse, mutect2, varscan2
- DOCK3 | c.2376C>T p.F792= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs776870372, COSV99814473; called by muse, mutect2, varscan2
- DPEP3 | c.777C>T p.N259= | Silent (SNP) | VAF 52/74 reads (70%) | catalogued as COSV99262855; called by muse, mutect2, varscan2
- DZIP1L | c.1194G>A p.Q398= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV59520726; called by muse, mutect2, varscan2
- FCRL5 | c.1428C>T p.T476= | Silent (SNP) | VAF 49/87 reads (56%) | catalogued as COSV100709257; called by muse, mutect2, varscan2
- FOXI1 | c.126C>T p.P42= | Silent (SNP) | VAF 10/10 reads (100%) | catalogued as COSV100089541; called by muse, mutect2, varscan2
- FZD2 | c.1476C>T p.R492= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV100190754; called by muse, mutect2, varscan2
- GPR139 | c.435C>T p.T145= | Silent (SNP) | VAF 77/128 reads (60%) | catalogued as rs1397326435, COSV100430009; called by muse, mutect2, varscan2
- GRIN2B | c.819C>T p.F273= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as COSV101663160; called by muse, mutect2, varscan2
- INTS14 | c.372G>A p.G124= (on ENST00000313182 / NM_001366360.2; = p.G45= on NM_001136043.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100500081; called by muse, mutect2, varscan2
- KIRREL2 | c.531G>A p.L177= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs769774142, COSV99384353; called by muse, mutect2, varscan2
- LCN2 | c.486G>A p.K162= | Silent (SNP) | VAF 18/24 reads (75%) | catalogued as COSV99478326; called by muse, mutect2, varscan2
- MAP3K13 | c.2361G>A p.E787= | Silent (SNP) | VAF 70/159 reads (44%) | catalogued as COSV99407778; called by muse, mutect2, varscan2
- MAPK8IP3 | c.492G>A p.L164= | Silent (SNP) | VAF 43/141 reads (30%) | catalogued as COSV99169615; called by muse, mutect2, varscan2
- MUC16 | c.36945G>A p.R12315= | Silent (SNP) | VAF 50/124 reads (40%) | catalogued as COSV67451634; called by muse, mutect2, varscan2
- MUC16 | c.4752C>T p.S1584= | Silent (SNP) | VAF 70/158 reads (44%) | catalogued as COSV101201162; called by muse, mutect2, varscan2
- MYO15A | c.6207C>T p.P2069= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV99234142; called by muse, mutect2, varscan2
- OR5K3 | c.69G>A p.L23= | Silent (SNP) | VAF 66/133 reads (50%) | catalogued as COSV101051673; called by muse, mutect2, varscan2
- PCDH15 | c.4374C>T p.F1458= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs267602528, COSV57267546; called by muse, mutect2, varscan2
- PDE11A | c.1212G>A p.E404= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV99614345; called by muse, mutect2, varscan2
- PPP1R12B | c.2574C>T p.A858= | Silent (SNP) | VAF 118/196 reads (60%) | catalogued as rs771631839, COSV51789552; called by muse, mutect2, varscan2
- PRDM9 | c.219C>T p.F73= | Silent (SNP) | VAF 23/29 reads (79%) | catalogued as COSV57011860, COSV99691058; called by muse, mutect2, varscan2
- PROSER2 | c.246C>T p.C82= | Silent (SNP) | VAF 39/44 reads (89%) | catalogued as rs150982968; called by muse, mutect2, varscan2
- RYR1 | c.5851C>T p.L1951= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV100616729; called by muse, mutect2, varscan2
- RYR3 | c.1449C>T p.A483= | Silent (SNP) | VAF 39/144 reads (27%) | catalogued as COSV101214044; called by muse, mutect2, varscan2
- SEC24C | c.1248C>T p.D416= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as COSV100227115; called by muse, mutect2, varscan2
- SGIP1 | c.1326C>T p.S442= | Silent (SNP) | VAF 104/254 reads (41%) | catalogued as COSV99392604; called by muse, mutect2, varscan2
- SPTAN1 | c.72C>T p.D24= | Silent (SNP) | VAF 28/34 reads (82%) | catalogued as COSV100823934; called by muse, mutect2, varscan2
- TCHH | c.4599C>T p.F1533= | Silent (SNP) | VAF 47/171 reads (27%) | catalogued as COSV100915323; called by muse, mutect2, varscan2
- TENT4B | c.813C>T p.D271= (on ENST00000561678 / NM_001365323.2; = p.D256= on NM_001040284.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/64 reads (95%) | catalogued as COSV100666150; called by muse, mutect2, varscan2
- TRABD2A | c.213C>T p.P71= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs778546730, COSV59106760; called by muse, varscan2
- TRPM6 | c.5049G>A p.R1683= | Silent (SNP) | VAF 24/28 reads (86%) | catalogued as rs1350209014, COSV62519015; called by muse, mutect2, varscan2
- UGT2B10 | c.1485C>T p.F495= | Silent (SNP) | VAF 60/160 reads (38%) | catalogued as COSV55322387; called by muse, mutect2, varscan2
- WDR88 | c.750G>A p.L250= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100866619; called by muse, mutect2, varscan2
- ZNF239 | c.84C>T p.S28= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV100021889; called by muse, mutect2, varscan2
- SPATA8 | n.757C>T | RNA (SNP) | VAF 58/81 reads (72%) | catalogued as rs1232742624, COSV60704178; called by muse, mutect2, varscan2
- TCP10L3 | n.2719+1157C>T | Intron (SNP) | VAF 39/94 reads (41%) | catalogued as COSV64750427; called by muse, mutect2, varscan2
- UGT1A6 | c.862-23304C>T | Intron (SNP) | VAF 91/195 reads (47%) | catalogued as rs189214805, COSV59381448; called by muse, mutect2, varscan2
